Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MT, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MT-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex: Male
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Recurrent melanoma (R) axilla - previous neg SNB. (R) axillary dissection.
Note: specimen cut into for tissue banking.

MACROSCOPIC DESCRIPTION

"CONTENTS RIGHT AXILLA DISSECTION". A large portion of fibrofatty tissue 200 x 140 x 70mm with a narrow ellipse of overlying skin 100 x 15mm. A portion of skeletal muscle 50 x 50 x 50mm is attached to one end of the specimen. In the center of the specimen there is a large nodule 50 x 40 x 30mm which has been incised prior to receipt. The large nodule has a whitish fleshy cut surface, and it is clear of resection margins macroscopically. Cut surface shows further multiple lymph nodes present. The specimen is dissected from the opposite end towards the muscle attached end, and the lymph nodes harvested are embedded in this order.

- A. Four nodes.
- B. One node bisected.
- C. Four nodes.
- D. One node bisected.
- E. Three nodes.
- F. One node divided.
- G. Four nodes.
- H. Four nodes.
- J. Three nodes.
- K. One node trisected.
- L. Representative sections of largest node.
- M. One node bisected.

1CD-0-3-
Melanoma, NOS 8720/3
Site: lymph node, axilla
C17.3
lw 8/24/11

MICROSCOPIC REPORT

Right axilla, lymph node dissection

Diagnosis: metastatic melanoma

Number of lymph nodes: identified 29; involved by metastatic melanoma: 1

Location of tumour: subcapsular parenchymal

Maximal size of largest tumour deposit: ~50mm, accounting for ~95% of the nodal cross-sectional area

Tumour description: pleomorphic, mitotically active epithelioid cells

Extranodal spread: not seen

SUMMARY

Right axilla, lymph node dissection

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

Metastatic melanoma in 1 of 29 lymph nodes.

REPORTED BY: Dr

Source: NCI Genomic Data Commons file b5be852e-4ee8-4b1c-9830-49849187d0b1 (TCGA-EE-A2MT.9AA313AC-45CD-437B-AB84-8FF08EAC1EE2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).